CPTAC case C3L-00453 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/90318dda-7722-45d9-a102-cc84e1d3f1bf

Demographics
Sex at birth: female; Race: white; Year of birth: 1970; Vital status: Dead; Days to death: 442 days (1.2 years); Year of death: 2018; Cause of death: Cancer Related; Country of birth: Russia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.9 years (17,114 days); Year of diagnosis: 2016; Days to last known disease status: 442 days (1.2 years); Progression or recurrence: yes; Days to recurrence: 213 days; Days to last follow up: 442 days (1.2 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 269 days; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 442 days (1.2 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 213 days; Karnofsky performance status: 70; ECOG performance status: 2.

Other clinical attributes
- Weight: 74 kg; Height: 169 cm; BMI: 25.91.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 10.5; Cigarettes per day: 10; Tobacco smoking onset year: 1990; Tobacco smoking quit year: 2011; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 21; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (6 samples)
- Sample C3L-00453-34: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC). An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample C3L-00453-50: Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Samples C3L-00453-51, C3L-00453-52 (2 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Sample C3L-00453-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Time between excision and freezing: 240 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample C3L-00453-57: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Time between excision and freezing: 240 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
